Somatic mutation profile of tumor specimen MMRF_1755_1_BM_CD138pos (aliquot MMRF_1755_1_BM_CD138pos_T1_KHS5U_L08693) from MMRF case MMRF_1755, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 78.4 years (28,627 days).
Specimen MMRF_1755_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6a20980-f363-4152-b55b-1b5c093cd6a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1755_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1755_1_PB_Whole_C3_KHS5U_L08692; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b8e253a-16c1-4043-bfa9-9d2ef2ca5085

The open-access MAF lists 202 somatic variants for this specimen: 94 protein-altering or splice-affecting, 32 silent, 76 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, 3'UTR 41, Silent 32, Intron 19, Splice Region 6, RNA 6, Nonsense Mutation 6, 3'Flank 5, Splice Site 3, 5'UTR 3, Frame Shift Del 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 49/73 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRF1 | c.281G>A p.C94Y | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100982615; called by muse, mutect2
- AHNAK | c.13165G>C p.D4389H | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99948915; called by muse, mutect2, varscan2
- AJAP1 | c.442C>A p.Q148K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.86); PolyPhen benign (0.024); catalogued as rs1381939975; called by muse, mutect2, varscan2
- ALB | c.1041G>T p.K347N | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs752053499; called by muse, mutect2, varscan2
- BAHCC1 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs781953437; called by muse, mutect2, varscan2
- C19orf67 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.271); catalogued as rs1215364661; called by muse, mutect2, varscan2
- C19orf67 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.147); catalogued as rs1312721794; called by muse, mutect2, varscan2
- DNAH12 | c.481C>A p.L161I | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV60858148, COSV60858769; called by muse, mutect2, varscan2
- EDA | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 62/69 reads (90%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.081); catalogued as rs1311978507; called by muse, varscan2
- EFNA5 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs774448128; called by muse, mutect2
- EML5 | c.952C>A p.L318I | Missense Mutation (SNP) | VAF 95/247 reads (38%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.997); catalogued as COSV100715005; called by muse, mutect2, varscan2
- ETNPPL | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs375895107; called by muse, mutect2, varscan2
- EVC | c.2448G>T p.Q816H | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs1342618312, COSV99381229; called by muse, mutect2
- FRMD7 | c.657G>C p.K219N | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM087851; called by muse, mutect2, varscan2
- FRRS1 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs1272819578; called by muse, mutect2
- GPR149 | c.385T>A p.Y129N | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV67667523; called by muse, mutect2, varscan2
- GRM5 | c.2609G>A p.G870D | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as rs1332950838; called by muse, mutect2, varscan2
- IGHJ3 | c.32T>A p.M11K | Missense Mutation (SNP) | VAF 36/38 reads (95%) | PolyPhen benign (0.007); catalogued as rs181332275; called by muse, varscan2
- IGLV2-23 | c.204G>C p.M68I | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs527928402; called by muse, mutect2, varscan2
- IGLV3-25 | c.47G>C p.G16A | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as rs369304140; called by muse, mutect2, varscan2
- KCNMA1 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.784); catalogued as rs776719617; called by muse, varscan2
- KDM3B | c.2022G>T p.W674C | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.85); catalogued as rs200872059; called by muse, mutect2, varscan2
- LCE2D | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.007); catalogued as rs372195789, COSV64229410; called by muse, mutect2, varscan2
- LMLN | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.023); catalogued as COSV54562025; called by muse, mutect2
- LRP1 | c.9939C>A p.H3313Q | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs931351039; called by muse, mutect2, varscan2
- MROH1 | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as COSV58188988; called by muse, mutect2, varscan2
- NOTCH3 | c.6380A>G p.Y2127C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.753); catalogued as COSV54642130; called by muse, mutect2, varscan2
- OR10AG1 | c.411A>G p.I137M | Missense Mutation (SNP) | VAF 152/243 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV100400246; called by muse, mutect2, varscan2
- PAPPA2 | c.1799G>T p.C600F | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100866787; called by muse, mutect2
- RYR3 | c.12619C>T p.Q4207* (on ENST00000389232; = p.Q4208* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 24/100 reads (24%) | catalogued as rs886568181; called by muse, mutect2, varscan2
- SLC2A7 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV101280812; called by muse, mutect2, varscan2
- STON2 | c.2426C>A p.S809Y (on ENST00000649389 / NM_001366849.2; = p.S752Y on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772529721, COSV50843028; called by muse, mutect2, varscan2
- TMEM63C | c.380A>G p.D127G | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs746683829; called by muse, mutect2, varscan2
- VWA5B2 | c.2029G>T p.G677C | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56610440; called by muse, mutect2, varscan2
- ZNF256 | c.914A>C p.N305T | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV56596906; called by muse, mutect2, varscan2
- ZNF469 | c.6256G>A p.A2086T (on ENST00000437464; = p.A2114T on NM_001367624.2) | Missense Mutation (SNP) | VAF 58/89 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1243898549; called by muse, mutect2, varscan2
- ABCA7 | c.350G>C p.S117T | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.05); called by muse, mutect2
- ALPL | c.190G>C p.V64L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ANK2 | c.11254G>T p.D3752Y | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ASB14 | c.1131T>G p.S377R | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- ATP11A | c.1395+2T>G p.X465_splice | Splice Site (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2
- BMPER | c.1252A>G p.T418A | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1QTNF12 | c.732G>C p.T244= | Splice Region (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- CDH19 | c.994A>C p.I332L | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- CNBD1 | c.771+5G>T | Splice Region (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.1268A>G p.E423G | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- CRTC2 | c.1464C>A p.Y488* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- CTC1 | c.2421G>C p.W807C | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTC1 | c.1302C>G p.F434L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- DYNC1I1 | c.1384G>A p.G462S | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- ENTPD7 | c.1519T>C p.Y507H | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ERCC4 | c.2024A>G p.Q675R | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- FAXDC2 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- FSCB | c.2398A>G p.T800A | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- GBP6 | c.239T>A p.M80K | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GPR39 | c.659T>C p.F220S | Missense Mutation (SNP) | VAF 147/353 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- HAUS8 | c.929+3A>G | Splice Region (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- HSD17B7 | c.238del p.R80Gfs*5 | Frame Shift Del (DEL) | VAF 30/294 reads (10%) | called by mutect2, pindel, varscan2
- HSD17B7P2 | n.781+2T>C | Splice Site (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- IGLV3-22 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.514); called by muse, mutect2
- KEL | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 141/218 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LRP12 | c.1472C>A p.T491K | Missense Mutation (SNP) | VAF 101/202 reads (50%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MED12L | c.5609C>G p.S1870C | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- MGAM2 | c.1988A>T p.N663I | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- MMP26 | c.400G>C p.V134L | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MOGS | c.2396A>T p.Y799F | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2
- MROH9 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- MRPS18C | c.153C>G p.P51= | Splice Region (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- MYSM1 | c.2270+2T>C p.X757_splice | Splice Site (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- NADK2 | c.712C>G p.L238V (on ENST00000381937 / NM_001085411.3; = p.L75V on NM_153013.4) | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NADSYN1 | c.45G>A p.W15* | Nonsense Mutation (SNP) | VAF 11/97 reads (11%) | called by mutect2, varscan2
- NRIP1 | c.3302A>T p.Q1101L | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2
- NUP210L | c.3181G>T p.V1061L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- OR4C13 | c.896T>A p.L299* | Nonsense Mutation (SNP) | VAF 26/148 reads (18%) | called by muse, mutect2, varscan2
- OTOP1 | c.687C>A p.H229Q | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHAC2 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- PDP1 | c.773del p.S258Ffs*65 | Frame Shift Del (DEL) | VAF 18/136 reads (13%) | called by mutect2, pindel, varscan2
- PDZRN3 | c.88A>G p.T30A | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- PHKA1 | c.1835G>T p.C612F | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT tolerated (0.39); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PLSCR3 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 45/91 reads (49%) | called by muse, mutect2, varscan2
- RAB6B | c.231C>G p.S77R | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF165 | c.484T>C p.W162R | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- RPGRIP1 | c.3376G>A p.A1126T | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- RYR2 | c.10636A>T p.K3546* | Nonsense Mutation (SNP) | VAF 51/286 reads (18%) | called by muse, mutect2, varscan2
- SIRT2 | c.64-8C>T | Splice Region (SNP) | VAF 83/173 reads (48%) | called by muse, mutect2, varscan2
- SNX15 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.58); called by muse, mutect2
- TENM2 | c.3633C>G p.I1211M (on ENST00000518659 / NM_001122679.2; = p.I979M on NM_001080428.3) | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TEX14 | c.1356T>C p.D452= (on ENST00000240361 / NM_001201457.2; = p.D446= on NM_031272.5) | Splice Region (SNP) | VAF 30/106 reads (28%) | called by muse, mutect2, varscan2
- TMEM132B | c.582C>A p.F194L | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2
- TTC6 | c.800A>C p.Q267P (on ENST00000267368; = p.Q1633P on NM_001310135.3) | Missense Mutation (SNP) | VAF 67/306 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.87998C>T p.T29333I (on ENST00000591111; = p.T21909I on NM_003319.4) | Missense Mutation (SNP) | VAF 12/110 reads (11%) | PolyPhen benign (0.039); called by muse, mutect2, varscan2
- WDR87 | c.7558G>C p.V2520L | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNF462 | c.6297G>T p.K2099N | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AATF | c.1308G>A p.G436= | Silent (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- BAIAP3 | c.1888C>T p.L630= | Silent (SNP) | VAF 22/111 reads (20%) | called by muse, mutect2, varscan2
- CEP152 | c.402T>C p.P134= | Silent (SNP) | VAF 11/189 reads (6%) | called by muse, mutect2
- CNTLN | c.825A>G p.K275= | Silent (SNP) | VAF 25/120 reads (21%) | called by muse, mutect2, varscan2
- COBLL1 | c.1125A>C p.A375= (on ENST00000392717; = p.A337= on NM_014900.5) | Silent (SNP) | VAF 26/77 reads (34%) | called by muse, mutect2, varscan2
- DLGAP2 | c.156G>A p.P52= | Silent (SNP) | VAF 36/47 reads (77%) | catalogued as rs777663374; called by muse, mutect2, varscan2
- DNAH10 | c.2670C>T p.V890= (on ENST00000409039; = p.V829= on NM_207437.3) | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs775853934; called by muse, varscan2
- DSEL | c.147A>C p.I49= | Silent (SNP) | VAF 127/219 reads (58%) | called by muse, mutect2, varscan2
- FMN2 | c.1536C>G p.G512= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV60459733; called by muse, mutect2, varscan2
- FRAS1 | c.519G>T p.R173= | Silent (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- HAS1 | c.1581C>A p.A527= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs773078452; called by muse, mutect2, varscan2
- IGHJ4 | c.46G>A p.*16= | Silent (SNP) | VAF 65/137 reads (47%) | catalogued as rs371664348; called by muse, varscan2
- IGLC2 | c.270G>C p.T90= | Silent (SNP) | VAF 53/132 reads (40%) | called by muse, varscan2
- IGSF9 | c.825G>A p.Q275= | Silent (SNP) | VAF 17/71 reads (24%) | called by muse, mutect2, varscan2
- ITIH5 | c.2127G>T p.L709= | Silent (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- LARGE1 | c.1725C>T p.Y575= | Silent (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- LHX5 | c.945C>A p.A315= | Silent (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- LRFN2 | c.2064C>A p.A688= | Silent (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- LRRC55 | c.432G>T p.L144= | Silent (SNP) | VAF 16/254 reads (6%) | catalogued as COSV73006629; called by muse, mutect2
- LY6K | c.93C>A p.S31= | Silent (SNP) | VAF 57/124 reads (46%) | catalogued as rs782453693; called by muse, mutect2, varscan2
- MYBPC3 | c.840T>C p.G280= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs1199652691; called by muse, mutect2, varscan2
- MYCN | c.999C>T p.A333= | Silent (SNP) | VAF 73/191 reads (38%) | catalogued as rs138606824; called by muse, mutect2, varscan2
- MYO15A | c.9147C>T p.C3049= | Silent (SNP) | VAF 27/89 reads (30%) | called by muse, mutect2, varscan2
- OR4F15 | c.702C>T p.A234= | Silent (SNP) | VAF 77/196 reads (39%) | called by muse, mutect2, varscan2
- PCDHB8 | c.2388C>T p.F796= | Silent (SNP) | VAF 11/133 reads (8%) | catalogued as COSV50825301, COSV99176442; called by muse, mutect2
- PRR23A | c.255G>A p.T85= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV67214318; called by muse, mutect2, varscan2
- RELN | c.72C>T p.R24= | Silent (SNP) | VAF 21/97 reads (22%) | called by muse, varscan2
- RIMS4 | c.270C>T p.D90= | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as rs746030392; called by muse, mutect2, varscan2
- RIOX1 | c.1128C>T p.N376= | Silent (SNP) | VAF 28/287 reads (10%) | called by muse, mutect2, varscan2
- TRIM7 | c.126C>T p.V42= | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- VIRMA | c.633T>A p.A211= | Silent (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- ZNF791 | c.1590G>A p.G530= | Silent (SNP) | VAF 26/352 reads (7%) | called by muse, mutect2
- AHNAK2 | c.*723T>G | 3'UTR (SNP) | VAF 84/166 reads (51%) | called by muse, mutect2, varscan2
- ALG10B | c.171+83A>T | Intron (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- ARRB1 | c.*1596G>A | 3'UTR (SNP) | VAF 57/148 reads (39%) | called by muse, mutect2, varscan2
- BTAF1 | c.*292G>A | 3'UTR (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- BUD31 | c.94+567G>A | Intron (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- CABP1 | c.*57T>C | 3'UTR (SNP) | VAF 41/118 reads (35%) | called by muse, mutect2, varscan2
- CACNG8 | c.*1120C>T | 3'UTR (SNP) | VAF 42/99 reads (42%) | catalogued as rs894558689; called by muse, mutect2, varscan2
- CARHSP1 | c.*561G>A | 3'UTR (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- CNTN1 | c.*291C>T | 3'UTR (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+11746G>A | Intron (SNP) | VAF 42/122 reads (34%) | catalogued as rs149702981; called by muse, mutect2, varscan2
- CUX1 | c.*3611C>G | 3'UTR (SNP) | VAF 29/146 reads (20%) | called by muse, mutect2, varscan2
- CXCL12 | c.266+744C>T | Intron (SNP) | VAF 14/57 reads (25%) | catalogued as rs777567895; called by muse, mutect2, varscan2
- CYP3A7 | c.219-118G>T | Intron (SNP) | VAF 30/98 reads (31%) | called by muse, mutect2, varscan2
- DCLK1 | c.*990G>A | 3'UTR (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- DDIT4L | c.*150C>G | 3'UTR (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- DTX1 | chr12:113057679 A>G | 5'Flank (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- EGLN3 | c.*1375del | 3'UTR (DEL) | VAF 20/108 reads (19%) | called by pindel, varscan2
- EIF1AD | c.*142G>C | 3'UTR (SNP) | VAF 14/217 reads (6%) | called by muse, mutect2
- ELF2P4 | n.227T>C | RNA (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- F13B | c.*138A>G | 3'UTR (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- FAM189A1 | c.*2241A>C | 3'UTR (SNP) | VAF 50/117 reads (43%) | called by muse, mutect2, varscan2
- FAM205BP | n.2619A>T | RNA (SNP) | VAF 34/261 reads (13%) | called by muse, mutect2, varscan2
- FOXA2 | c.-1-156G>A | Intron (SNP) | VAF 32/48 reads (67%) | catalogued as rs934004894; called by muse, mutect2, varscan2
- H2AC21 | c.*4A>C | 3'UTR (SNP) | VAF 115/267 reads (43%) | called by muse, mutect2, varscan2
- HMGA2 | c.249+19283A>T | Intron (SNP) | VAF 30/96 reads (31%) | called by muse, mutect2, varscan2
- HNRNPU | chr1:244852292 C>T | 3'Flank (SNP) | VAF 44/107 reads (41%) | called by muse, mutect2, varscan2
- HYDIN2 | n.4948A>G | RNA (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- INPP5J | c.*74C>G | 3'UTR (SNP) | VAF 27/121 reads (22%) | called by muse, mutect2, varscan2
- JPH3 | chr16:87701006 C>A | 3'Flank (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- LCORL | c.*1412T>G | 3'UTR (SNP) | VAF 19/101 reads (19%) | called by muse, varscan2
- LILRB4 | chr19:54669271 C>T | 3'Flank (SNP) | VAF 9/33 reads (27%) | catalogued as rs1180771999; called by muse, mutect2, varscan2
- LINC00602 | n.739C>A | RNA (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- LINC02873 | n.1270T>C | RNA (SNP) | VAF 18/130 reads (14%) | called by muse, mutect2, varscan2
- LINC02873 | n.1712C>A | RNA (SNP) | VAF 67/194 reads (35%) | called by muse, mutect2, varscan2
- LMBR1 | c.*1315C>T | 3'UTR (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- LRRC4B | c.*11C>A | 3'UTR (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100975909; called by muse, mutect2, varscan2
- LTB | c.163-45A>G | Intron (SNP) | VAF 177/380 reads (47%) | called by muse, varscan2
- MBTPS2 | c.970+1655C>T | Intron (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- MGAM | c.*839A>G | 3'UTR (SNP) | VAF 40/70 reads (57%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851168 T>G | 5'Flank (SNP) | VAF 83/165 reads (50%) | called by muse, mutect2, varscan2
- MOB3B | c.*747T>A | 3'UTR (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- MOG | c.*294G>A | 3'UTR (SNP) | VAF 30/275 reads (11%) | called by muse, mutect2, varscan2
- MPP7 | c.*974T>C | 3'UTR (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- MVB12B | c.*697G>A | 3'UTR (SNP) | VAF 14/235 reads (6%) | called by muse, mutect2
- NEK9 | c.1731+57T>G | Intron (SNP) | VAF 31/110 reads (28%) | called by muse, mutect2, varscan2
- NF1 | c.*1476G>C | 3'UTR (SNP) | VAF 5/54 reads (9%) | called by muse, varscan2
- NIPA2 | c.197-49G>C | Intron (SNP) | VAF 12/106 reads (11%) | catalogued as rs1002658989; called by muse, mutect2, varscan2
- NNMT | c.*557A>T | 3'UTR (SNP) | VAF 21/137 reads (15%) | catalogued as rs1003467772; called by muse, mutect2, varscan2
- NPL | c.230+40A>C | Intron (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- NRG3 | c.823+1857G>A | Intron (SNP) | VAF 35/107 reads (33%) | catalogued as rs575183698, COSV64554163; called by muse, mutect2, varscan2
- PCF11 | c.2092+373A>G | Intron (SNP) | VAF 25/124 reads (20%) | called by muse, mutect2, varscan2
- PHF14 | c.-123C>T | 5'UTR (SNP) | VAF 45/203 reads (22%) | called by muse, mutect2, varscan2
- PID1 | chr2:229024734 G>T | 3'Flank (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- PPP1R9A | c.*2149G>C | 3'UTR (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- PRKAA2 | c.*5435C>G | 3'UTR (SNP) | VAF 19/71 reads (27%) | called by muse, mutect2, varscan2
- RPL19 | c.468-70G>A | Intron (SNP) | VAF 58/153 reads (38%) | catalogued as rs1017689399; called by muse, mutect2, varscan2
- RTP1 | c.*1043C>G | 3'UTR (SNP) | VAF 16/70 reads (23%) | called by mutect2, varscan2
- RUNX1T1 | c.88+13168C>G | Intron (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- SEMA4F | c.*1025A>G | 3'UTR (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- SF1 | c.*888C>T | 3'UTR (SNP) | VAF 15/79 reads (19%) | catalogued as rs1321407664; called by muse, mutect2, varscan2
- SKP2 | c.*975A>T | 3'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, varscan2
- SLC26A11 | c.*215G>A | 3'UTR (SNP) | VAF 45/158 reads (28%) | catalogued as rs568961616; called by muse, mutect2, varscan2
- SLC33A1 | c.-84G>A | 5'UTR (SNP) | VAF 62/184 reads (34%) | called by muse, mutect2, varscan2
- SLC66A1L | n.225-1762C>T | Intron (SNP) | VAF 77/554 reads (14%) | called by muse, varscan2
- SNX6 | c.*1035G>C | 3'UTR (SNP) | VAF 14/70 reads (20%) | called by mutect2, varscan2
- STPG2 | c.*2427C>A | 3'UTR (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- SUN1 | c.*515C>T | 3'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- TOPAZ1 | c.-143G>T | 5'UTR (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100555487; called by muse, mutect2, varscan2
- TP63 | c.1350-5391C>A | Intron (SNP) | VAF 8/192 reads (4%) | catalogued as rs1015961274; called by muse, mutect2
- USP20 | c.*710G>T | 3'UTR (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- VKORC1L1 | c.*739G>T | 3'UTR (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- Z83844.2 | c.282-68T>G | Intron (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- ZNF12 | c.*1944C>T | 3'UTR (SNP) | VAF 12/132 reads (9%) | catalogued as rs956394145; called by muse, mutect2
- ZNF260 | c.*1507C>T | 3'UTR (SNP) | VAF 53/133 reads (40%) | called by muse, mutect2, varscan2
- ZNF697 | c.*2227T>A | 3'UTR (SNP) | VAF 25/114 reads (22%) | called by muse, mutect2, varscan2
- ZSWIM4 | chr19:13836517 G>A | 3'Flank (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
